Somatic mutation profile of tumor specimen C3L-03717-01 (aliquot CPT0234740006) from CPTAC case C3L-03717, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G1; Age at diagnosis: 54.3 years (19,827 days).
Specimen C3L-03717-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01ce841c-145c-4397-ae12-a3b086365633.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03717-31 (Blood Derived Normal), aliquot CPT0235690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6285a5d-d225-45aa-b595-022476694ffb

The open-access MAF lists 58 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 11, Nonsense Mutation 4, Intron 3, RNA 1, Splice Region 1, 3'Flank 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 6/144 reads (4%) | hotspot (GDC flag); catalogued as COSV58820842, COSV58825712; called by muse, mutect2
- ABHD12 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 21/348 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs763733941; called by muse, mutect2
- CLTCL1 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.493); catalogued as COSV54236080; called by muse, mutect2
- ERICH1 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as rs1387965965, COSV50641104; called by muse, mutect2
- F13A1 | c.1298T>C p.F433S | Missense Mutation (SNP) | VAF 65/531 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53553146; called by muse, mutect2, varscan2
- MED12 | c.151G>T p.V51F | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV61338246; called by muse, mutect2
- PAPPA2 | c.1921G>T p.D641Y | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV62785060; called by muse, mutect2, varscan2
- REPIN1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 44/536 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777503977; called by muse, mutect2
- TOX2 | c.328C>T p.P110S (on ENST00000358131 / NM_001098798.2; = p.P59S on NM_032883.3) | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.906); catalogued as COSV57888477; called by muse, mutect2
- ABCG2 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2
- ALPK2 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- APCS | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.393); called by muse, mutect2
- C20orf194 | c.2008del p.Q670Kfs*15 | Frame Shift Del (DEL) | VAF 12/113 reads (11%) | called by mutect2, pindel, varscan2
- CNTN1 | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 22/478 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.251); called by muse, mutect2
- CRACD | c.2450C>A p.T817K | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT tolerated (0.91); PolyPhen benign (0.041); called by muse, mutect2
- DHTKD1 | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- DOCK3 | c.4778T>A p.L1593H | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- F8 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2
- FBLN5 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 30/538 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPT | c.395T>A p.I132N | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HAUS7 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2
- IRAK2 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.389); called by muse, mutect2
- KLHL2 | c.1163A>T p.D388V | Missense Mutation (SNP) | VAF 18/403 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.055); called by muse, mutect2
- KRT39 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 9/189 reads (5%) | called by muse, mutect2
- KRTAP13-1 | c.483C>A p.C161* | Nonsense Mutation (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- LINGO1 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC4C | c.1269G>A p.M423I | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- MGAT5B | c.2102C>A p.T701N (on ENST00000569840 / NM_001199172.2; = p.T699N on NM_144677.3) | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.322); called by muse, mutect2
- MMUT | c.2137C>G p.L713V | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- NFATC2 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.079); called by muse, mutect2
- NXF1 | c.1017-3C>T | Splice Region (SNP) | VAF 11/221 reads (5%) | called by muse, mutect2
- REX1BD | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- SETD5 | c.1004A>C p.E335A | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- SMCHD1 | c.2291A>T p.H764L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); called by muse, mutect2
- SYT13 | c.172T>C p.S58P | Missense Mutation (SNP) | VAF 22/550 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- TET2 | c.2170C>T p.H724Y | Missense Mutation (SNP) | VAF 31/560 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2
- TMEM205 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2
- TNIK | c.1616A>G p.E539G | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- UBR4 | c.5548A>G p.K1850E | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- WDR19 | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.281); called by muse, mutect2
- XIRP2 | c.8422A>G p.I2808V (on ENST00000628543; = p.I2983V on NM_152381.6) | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS12 | c.4365T>C p.C1455= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- ATP8B2 | c.1302C>T p.I434= (on ENST00000672630; = p.I401= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 34/308 reads (11%) | called by muse, mutect2, varscan2
- CCAR1 | c.276T>C p.Y92= | Silent (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- CDH6 | c.864C>T p.G288= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as rs771132300; called by mutect2, varscan2
- FGF13 | c.105C>A p.S35= | Silent (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- GGN | c.726G>A p.L242= | Silent (SNP) | VAF 18/636 reads (3%) | catalogued as rs1340812603; called by muse, mutect2
- IMPDH2 | c.558G>A p.V186= | Silent (SNP) | VAF 19/362 reads (5%) | catalogued as rs762293465; called by muse, mutect2
- KIAA0319L | c.72T>G p.S24= | Silent (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- SCARA5 | c.432C>T p.G144= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as rs1205626916; called by muse, mutect2
- SLC2A1 | c.831G>C p.V277= | Silent (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2, varscan2
- TMEM178B | c.570G>T p.V190= | Silent (SNP) | VAF 14/376 reads (4%) | called by muse, mutect2
- FAM220BP | n.380G>T | RNA (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- HAUS1 | c.-6G>T | 5'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- PMS2 | c.537+16C>T | Intron (SNP) | VAF 19/187 reads (10%) | catalogued as rs1057521052; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR2 | c.11146-1206A>T | Intron (SNP) | VAF 14/151 reads (9%) | called by muse, mutect2
- SNORD116-17 | chr15:25088636 G>T | 3'Flank (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- SPEF2 | c.4448-3922T>A | Intron (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
